Somatic mutation profile of tumor specimen TCGA-BQ-7048-01A (aliquot TCGA-BQ-7048-01A-11D-1961-08) from TCGA case TCGA-BQ-7048, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 64.2 years (23,460 days).
Specimen TCGA-BQ-7048-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79bd636f-4389-4bcf-abab-42d2e20b73c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-7048-11A (Solid Tissue Normal), aliquot TCGA-BQ-7048-11A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/438954b0-4af9-41f4-b07c-fd37a6660308

The open-access MAF lists 67 somatic variants for this specimen: 47 protein-altering or splice-affecting, 16 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 16, Splice Site 5, Frame Shift Del 5, Nonsense Mutation 3, Intron 2, In Frame Del 2, Translation Start Site 1, 3'UTR 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.3517A>T p.S1173C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV64677223; called by muse, mutect2, varscan2
- ACSL1 | c.195+2T>A p.X65_splice | Splice Site (SNP) | VAF 8/12 reads (67%) | catalogued as COSV55666079; called by muse, mutect2, varscan2
- ADD3 | c.568-2A>G p.X190_splice | Splice Site (SNP) | VAF 32/72 reads (44%) | catalogued as COSV53325385; called by muse, mutect2, varscan2
- ANK3 | c.10996A>G p.T3666A | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV55078240; called by muse, mutect2, varscan2
- ATP10A | c.2023G>T p.D675Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as COSV100791559, COSV63522916; called by mutect2, varscan2
- CYP1B1 | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.557); catalogued as rs1384370014, COSV53192647; called by muse, mutect2, varscan2
- DAB2IP | c.740G>T p.G247V (on ENST00000408936; = p.G219V on NM_032552.3) | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV52266924; called by muse, mutect2, varscan2
- DNM3 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.038); catalogued as COSV62465794; called by muse, mutect2, varscan2
- EMC1 | c.920A>G p.Y307C | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.112); catalogued as COSV61887065; called by muse, mutect2, varscan2
- FGF1 | c.454G>T p.V152F | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV100532286, COSV61804518; called by muse, mutect2, varscan2
- GFI1 | c.118A>G p.S40G | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV54043784; called by muse, mutect2, varscan2
- HSF5 | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | catalogued as COSV60203192; called by mutect2, varscan2
- KLHDC1 | c.698C>G p.T233S | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV63779250; called by muse, mutect2, varscan2
- KMT2D | c.5291T>C p.L1764P | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56480161; called by muse, mutect2, varscan2
- LGI4 | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 21/321 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59534844; called by muse, mutect2
- LRRC8D | c.1132T>A p.F378I | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV61580944; called by muse, mutect2, varscan2
- MTUS1 | c.2320T>C p.S774P | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); catalogued as COSV50582218; called by muse, mutect2, varscan2
- MYCT1 | c.518G>T p.C173F | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV65891857; called by muse, mutect2, varscan2
- NPL | c.164G>C p.G55A | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1406848059, COSV51127380; called by muse, mutect2, varscan2
- OR5T3 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV100282703, COSV57382318; called by muse, mutect2, varscan2
- PAGR1 | c.689C>G p.S230W | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV56191359; called by muse, mutect2, varscan2
- PRICKLE2 | c.2537T>C p.F846S (on ENST00000295902; = p.F790S on NM_198859.4) | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55770998; called by muse, mutect2, varscan2
- RNF157 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 25/58 reads (43%) | catalogued as COSV53947806; called by muse, mutect2, varscan2
- SEL1L3 | c.1678T>A p.F560I | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs938835580, COSV53548438; called by muse, mutect2, varscan2
- SMARCB1 | c.425C>T p.P142L (on ENST00000263121; = p.P188L on NM_003073.5) | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs137986695, COSV54095792; called by muse, mutect2
- TBL2 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1563451777, COSV59788146; called by muse, varscan2
- TGFBR1 | c.490C>G p.P164A | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.127); catalogued as COSV66626811; called by muse, mutect2, varscan2
- TMC6 | c.1804C>G p.L602V | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59809995, COSV59811031; called by muse, mutect2, varscan2
- TNPO1 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV61523656; called by muse, mutect2, varscan2
- TTC17 | c.842C>A p.A281D | Missense Mutation (SNP) | VAF 109/236 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50018307; called by muse, varscan2
- TTF2 | c.2515A>T p.K839* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV65633509, COSV65634009; called by muse, mutect2, varscan2
- TTLL2 | c.1648G>T p.D550Y | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV53443458, COSV53445556; called by muse, mutect2, varscan2
- WDR33 | c.273+1G>T p.X91_splice | Splice Site (SNP) | VAF 42/111 reads (38%) | catalogued as COSV59254834; called by muse, mutect2, varscan2
- XPO5 | c.225C>G p.V75= | Splice Region (SNP) | VAF 186/364 reads (51%) | catalogued as COSV54834335; called by muse, varscan2
- ZBTB46 | c.656G>C p.G219A | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs776087199, COSV55514147; called by muse, mutect2, varscan2
- ZNF335 | c.3206A>G p.H1069R | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59819867; called by muse, mutect2, varscan2
- ZNF423 | c.2219A>T p.K740M (on ENST00000563137 / NM_001379286.1; = p.K732M on NM_015069.4) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52202220; called by mutect2, varscan2
- AUTS2 | c.3636del p.P1213Rfs*5 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- BCL2L11 | c.499-2_505del p.X167_splice (on ENST00000393256 / NM_138621.5; = p.X107_splice on NM_006538.5) | Splice Site (DEL) | VAF 15/56 reads (27%) | called by mutect2, pindel, varscan2
- CLTA | c.640del p.V214Wfs*49 (on ENST00000242285 / NM_007096.4; = p.V184Wfs*49 on NM_001833.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 34/103 reads (33%) | called by mutect2, pindel, varscan2
- FNIP1 | c.2758_2759del p.S920Ffs*3 | Frame Shift Del (DEL) | VAF 44/140 reads (31%) | called by pindel, varscan2
- KCTD4 | c.434_436del p.I145del | In Frame Del (DEL) | VAF 14/156 reads (9%) | called by mutect2, pindel
- MRTFA | c.1200_1202del p.G401del | In Frame Del (DEL) | VAF 36/86 reads (42%) | called by mutect2, pindel, varscan2
- SERPINB11 | c.247del p.I83Ffs*40 | Frame Shift Del (DEL) | VAF 40/123 reads (33%) | called by mutect2, pindel, varscan2
- STOX2 | c.1865del p.E622Gfs*6 | Frame Shift Del (DEL) | VAF 7/67 reads (10%) | called by mutect2, pindel, varscan2
- TRIP12 | c.1008-2_1008del p.X336_splice | Splice Site (DEL) | VAF 18/36 reads (50%) | called by mutect2, pindel, varscan2
- WDR33 | c.2842C>T p.P948S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.026); called by muse, mutect2
- C12orf54 | c.255T>C p.P85= | Silent (SNP) | VAF 68/162 reads (42%) | catalogued as rs745513443, COSV58360020; called by muse, mutect2, varscan2
- C1QTNF5 | c.702C>G p.S234= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV60991346; called by muse, mutect2, varscan2
- CNOT2 | c.132C>T p.Y44= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs1263976015, COSV57506347; called by muse, mutect2, varscan2
- ESR1 | c.747A>G p.G249= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV52800499; called by muse, mutect2, varscan2
- GPR142 | c.789C>A p.P263= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV59519838; called by mutect2, varscan2
- KRTAP27-1 | c.162C>T p.C54= | Silent (SNP) | VAF 46/134 reads (34%) | catalogued as COSV67001570; called by muse, mutect2, varscan2
- LATS1 | c.855C>A p.I285= | Silent (SNP) | VAF 72/158 reads (46%) | catalogued as COSV53598627; called by muse, mutect2, varscan2
- LRP6 | c.3006G>A p.V1002= | Silent (SNP) | VAF 103/238 reads (43%) | catalogued as rs774775488, COSV53793167; called by muse, mutect2, varscan2
- MESD | c.96C>T p.C32= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV55726368; called by muse, varscan2
- MICAL2 | c.4998C>T p.D1666= | Silent (SNP) | VAF 61/166 reads (37%) | catalogued as COSV56288268; called by muse, mutect2, varscan2
- NFKBIA | c.399T>C p.A133= | Silent (SNP) | VAF 7/132 reads (5%) | catalogued as COSV53754598; called by muse, mutect2
- PLD1 | c.2001C>T p.F667= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV60573336; called by muse, mutect2, varscan2
- RBM45 | c.282C>T p.N94= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV53722348; called by mutect2, varscan2
- SCYL3 | c.1461T>A p.T487= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV53682253; called by muse, mutect2, varscan2
- SFTPD | c.429C>G p.P143= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV64853666; called by muse, mutect2, varscan2
- XKR3 | c.414C>A p.I138= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as COSV58887761; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1474G>A | Intron (SNP) | VAF 37/135 reads (27%) | catalogued as COSV63754496; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500313 T>C | 5'Flank (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- BOLA3 | c.*34G>T | 3'UTR (SNP) | VAF 28/95 reads (29%) | catalogued as COSV99768269; called by muse, mutect2, varscan2
- KPNA4 | c.1032+279T>C | Intron (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100515376; called by muse, mutect2, varscan2
